Somatic mutation profile of tumor specimen TCGA-EY-A1GS-01A (aliquot TCGA-EY-A1GS-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.2 years (26,012 days).
Specimen TCGA-EY-A1GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1375fd52-c794-449f-a96f-49ba6388dcab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GS-10A (Blood Derived Normal), aliquot TCGA-EY-A1GS-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0415221-9b26-4566-832d-f1fecd8c5344

The open-access MAF lists 385 somatic variants for this specimen: 298 protein-altering or splice-affecting, 81 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 81, Nonsense Mutation 28, Splice Site 6, In Frame Del 3, Frame Shift Del 3, Intron 2, 5'Flank 1, In Frame Ins 1, 5'UTR 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.1838-1G>A p.X613_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as rs1555399840, CS042163, CS161882, COSV57319905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 40/43 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- AASS | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62790581; called by muse, mutect2, varscan2
- ABLIM1 | c.2300G>C p.R767T | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV99522652; called by muse, mutect2
- ACTG1 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59510922; called by muse, mutect2, varscan2
- ADGRB3 | c.4275+1G>A p.X1425_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV53249931; called by muse, mutect2, varscan2
- ADGRG4 | c.7756G>A p.E2586K | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); catalogued as rs865865544, COSV54959764; called by muse, mutect2, varscan2
- ADSS1 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV100272528, COSV58274324; called by muse, mutect2, varscan2
- AL592490.1 | c.2221C>G p.L741V | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV101308268; called by muse, mutect2
- ANKRD44 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56553582; called by muse, mutect2
- ANKS1B | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61352854, COSV61358415; called by muse, mutect2, varscan2
- ARHGAP17 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV51508953; called by muse, mutect2, varscan2
- ARHGAP35 | c.192del p.R66Efs*105 | Frame Shift Del (DEL) | VAF 35/83 reads (42%) | catalogued as COSV68332642; called by mutect2, pindel, varscan2
- ARPC4 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV55028854; called by muse, mutect2
- ASTL | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100668243; called by muse, mutect2
- ASXL3 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52470303; called by muse, mutect2, varscan2
- BMP10 | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.087); catalogued as COSV54895778; called by muse, mutect2, varscan2
- BRD1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53455180, COSV99350206; called by muse, mutect2
- BTBD3 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs779571712, COSV54779946; called by muse, mutect2, varscan2
- BTN2A1 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV57004206; called by muse, mutect2, varscan2
- C1QTNF3 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51469099; called by muse, mutect2, varscan2
- C1orf189 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV63891036; called by muse, mutect2
- CAB39 | c.396A>C p.K132N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV51477411; called by muse, mutect2, varscan2
- CADPS | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs141301525, COSV51881188; called by muse, mutect2, varscan2
- CBX6 | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV53321202; called by muse, mutect2, varscan2
- CC2D1B | c.1538C>A p.S513* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52560979; called by muse, mutect2, varscan2
- CCDC60 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs1350115189, COSV59543390; called by muse, mutect2, varscan2
- CD99 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); catalogued as rs776195577, COSV101152335; called by muse, mutect2, varscan2
- CDH15 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57025267; called by muse, mutect2, varscan2
- CHN1 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99789400; called by muse, mutect2
- CLDN12 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs200372770, COSV55306578; called by muse, mutect2, varscan2
- CNTNAP5 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as COSV70472977, COSV70492625; called by muse, mutect2, varscan2
- COG1 | c.2765G>C p.R922P | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55429754, COSV55430498; called by muse, mutect2, varscan2
- COL4A4 | c.3911G>C p.G1304A | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306904, COSV61633484; called by muse, mutect2, varscan2
- COX6A1 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs767207473, COSV57569438, COSV57569488, COSV57569746; called by muse, mutect2, varscan2
- CPNE9 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV56068939; called by muse, mutect2, varscan2
- CR1L | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.403); catalogued as COSV54327725; called by muse, mutect2, varscan2
- CRLF3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs373829171, COSV60835410; called by muse, mutect2, varscan2
- CSPG4 | c.5593C>G p.P1865A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV57897189; called by muse, mutect2, varscan2
- CTSK | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99067889; called by muse, mutect2
- CUL1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV57386978; called by muse, mutect2, varscan2
- CYLD | c.2210C>G p.S737C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61095611; called by muse, mutect2, varscan2
- CYP4F12 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs1273708026, COSV61174566; called by muse, mutect2, varscan2
- DCP1A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV99588199; called by muse, mutect2, varscan2
- DCP1A | c.1049G>C p.R350T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV53688555; called by muse, mutect2
- DDX11 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV52504451, COSV52506209; called by muse, mutect2, varscan2
- DDX28 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV60105856; called by muse, mutect2, varscan2
- DGKH | c.2551C>A p.P851T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV54930723, COSV54934707; called by muse, mutect2, varscan2
- DIP2C | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.285); catalogued as COSV99792918; called by muse, mutect2
- DLD | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52738575; called by muse, mutect2, varscan2
- DMD | c.6103G>A p.E2035K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as CM098432, COSV63733752; called by muse, mutect2, varscan2
- DNAH1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771932160; called by mutect2, varscan2
- DNAH1 | c.2853G>C p.E951D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV70230902; called by muse, mutect2, varscan2
- DOCK11 | c.5271G>C p.K1757N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99354479; called by muse, mutect2
- DPP6 | c.577G>A p.E193K (on ENST00000377770 / NM_001364500.2; = p.E131K on NM_001936.5) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs186683462, COSV59623612; called by muse, mutect2, varscan2
- DYSF | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV50455273; called by muse, mutect2, varscan2
- EEF1G | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as COSV100240412, COSV57746933; called by muse, mutect2, varscan2
- EFR3A | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54461745; called by muse, mutect2
- EML3 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53872340; called by muse, mutect2
- EPHX4 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV64889651, COSV64889718; called by muse, mutect2, varscan2
- EPN3 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV99277330; called by muse, mutect2, varscan2
- ERBIN | c.4097C>G p.S1366* (on ENST00000284037 / NM_001253697.2; = p.S1325* on NM_018695.4) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV52319899; called by muse, mutect2, varscan2
- ERCC6 | c.2859G>C p.Q953H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63391530; called by muse, mutect2, varscan2
- F11 | c.756-1G>C p.X252_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53004293, COSV53007583; called by muse, mutect2, varscan2
- FAM13A | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV52001399, COSV52005448; called by muse, mutect2, varscan2
- FAM172A | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101232708, COSV67939021; called by muse, mutect2, varscan2
- FAM83D | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54157981; called by muse, mutect2, varscan2
- FBXL13 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as COSV100502034; called by muse, mutect2
- FBXO47 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); catalogued as COSV100960802; called by muse, mutect2
- FDPS | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV63114848; called by muse, mutect2, varscan2
- FLG | c.4371G>T p.Q1457H | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100912034; called by muse, mutect2
- FLG | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 19/258 reads (7%) | catalogued as COSV100912035, COSV64249637; called by muse, mutect2
- FMO5 | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as COSV54206583, COSV99567394; called by muse, mutect2
- G3BP1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 28/342 reads (8%) | catalogued as COSV100664036, COSV100664040; called by muse, mutect2
- GBF1 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100890646; called by muse, mutect2
- GEMIN5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53559628, COSV53561411; called by muse, mutect2
- GLIPR1 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV56990208, COSV56991610; called by muse, mutect2, varscan2
- GLIS2 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99267531; called by muse, mutect2
- GON4L | c.5481G>C p.K1827N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753140395, COSV55203425; called by muse, mutect2
- GPX2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63036403; called by muse, mutect2, varscan2
- GRIK1 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV100516902, COSV100517734, COSV58711969; called by muse, mutect2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- GULP1 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV63069086; called by muse, mutect2, varscan2
- GZMA | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57113620; called by muse, mutect2, varscan2
- H2BC9 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55100180; called by muse, varscan2
- H2BC9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV55099863, COSV55100002; called by muse, varscan2
- H2BC9 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV55099027, COSV55099687, COSV99769055; called by muse, varscan2
- HERC1 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV71248550; called by muse, mutect2, varscan2
- HEXB | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99784443; called by muse, mutect2
- HPS4 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV61104047; called by muse, mutect2, varscan2
- HUWE1 | c.8035G>C p.E2679Q | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99473949; called by muse, mutect2
- IL17RC | c.1423C>T p.Q475* (on ENST00000295981 / NM_153461.4; = p.Q389* on NM_032732.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55973713; called by muse, mutect2, varscan2
- IL6 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1008485748, COSV51733154; called by muse, mutect2, varscan2
- IPO8 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs746637703, COSV56242845; called by muse, mutect2, varscan2
- ITGA6 | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51230486; called by muse, mutect2, varscan2
- ITGB4 | c.3306C>G p.I1102M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV52328448; called by muse, mutect2, varscan2
- JAM2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV57258392; called by muse, mutect2, varscan2
- KDM1B | c.1865A>C p.Q622P (on ENST00000449850; = p.Q389P on NM_153042.4) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV52812002; called by muse, mutect2, varscan2
- KDM5C | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64762900; called by muse, mutect2, varscan2
- KHDC4 | c.1614G>C p.R538S | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV64167258; called by muse, mutect2, varscan2
- KIF15 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1400102912, COSV58162062; called by muse, mutect2, varscan2
- KIF2C | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777985755, COSV64764388; called by muse, mutect2, varscan2
- KIF4B | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101469394; called by muse, mutect2
- KLHDC1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.231); catalogued as COSV63778937; called by muse, mutect2, varscan2
- LCE2C | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV64228491, COSV64228610; called by muse, mutect2
- LCE3A | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); catalogued as rs761525258, COSV59550792; called by muse, mutect2, varscan2
- LCOR | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV53716812; called by muse, mutect2, varscan2
- LDB2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1217816744, COSV58772553; called by muse, mutect2, varscan2
- LIG1 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV54393037; called by muse, mutect2, varscan2
- LMCD1 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50089078; called by muse, varscan2
- LRFN5 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770689533, COSV53262520; called by muse, mutect2, varscan2
- LRP6 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.118); catalogued as COSV53789495, COSV99743626; called by muse, mutect2, varscan2
- LRRC14 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV52880294; called by mutect2, varscan2
- MAGEL2 | c.3053C>G p.S1018C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV58567729; called by muse, mutect2, varscan2
- MCTP2 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV100537687; called by muse, mutect2
- MEA1 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV55145413; called by muse, mutect2, varscan2
- MRPL35 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1477951805, COSV54485632; called by muse, mutect2, varscan2
- MYC | c.21C>G p.F7L (on ENST00000377970; = p.F22L on NM_002467.6) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52369158, COSV52374846; called by muse, mutect2, varscan2
- MYH1 | c.5280G>C p.K1760N | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56851185; called by muse, mutect2, varscan2
- MYH15 | c.3983G>A p.R1328K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56313203; called by muse, mutect2, varscan2
- MYLK | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100659532; called by muse, mutect2
- MYO3B | c.3615C>G p.I1205M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as COSV58707501, COSV58719269; called by muse, mutect2, varscan2
- MYO9B | c.2772G>A p.M924I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV101261841; called by muse, mutect2
- NABP2 | c.291-1G>C p.X97_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV57191025, COSV57192282; called by muse, mutect2, varscan2
- NCAPG | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52271007, COSV99265601; called by muse, mutect2, varscan2
- NCOA6 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV62863709; called by muse, mutect2
- NELL2 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61577843; called by muse, mutect2, varscan2
- NFKBIA | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV53753002; called by muse, mutect2, varscan2
- NID2 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.272); catalogued as rs745564706, COSV53498314; called by muse, mutect2, varscan2
- NLRC3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57092442; called by muse, mutect2, varscan2
- NOTCH2 | c.3470C>A p.P1157H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56694874; called by muse, mutect2, varscan2
- NRAP | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1170026245, COSV63491756; called by muse, mutect2, varscan2
- NRIP1 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59658290; called by muse, mutect2, varscan2
- NRIP1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as rs776680141, COSV59658295; called by muse, mutect2, varscan2
- OR2T12 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs200352170, COSV58776065, COSV58778849; called by muse, mutect2
- OR51G1 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 31/42 reads (74%) | catalogued as rs147041921; called by muse, mutect2, varscan2
- OR8D2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV62488627; called by muse, mutect2, varscan2
- OSER1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs755382758, COSV54854000; called by muse, mutect2, varscan2
- OVCH1 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV58964755; called by muse, mutect2, varscan2
- PADI4 | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.652); catalogued as COSV64924283; called by muse, mutect2, varscan2
- PAF1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs754420217, COSV55394879; called by muse, mutect2, varscan2
- PBX4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV52062188; called by muse, mutect2, varscan2
- PCLO | c.9840G>C p.M3280I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs745372105, COSV61638945, COSV61643905, COSV61661151; called by muse, mutect2, varscan2
- PCNX3 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs1353193775, COSV100482701; called by muse, mutect2
- PDCD2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as COSV99388542; called by muse, mutect2
- PDE4DIP | c.4487G>A p.R1496K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV100521366; called by muse, mutect2, varscan2
- PDE8B | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs144671246, COSV53736442; called by mutect2, varscan2
- PDGFB | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs150560474; called by muse, mutect2, varscan2
- PGBD4 | c.734G>C p.R245T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV56628205; called by muse, mutect2, varscan2
- PIBF1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58324688; called by muse, mutect2, varscan2
- PKHD1L1 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.647); catalogued as rs1471090292; called by muse, mutect2, varscan2
- PLIN4 | c.326G>T p.G109V (on ENST00000301286; = p.G124V on NM_001367868.2) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV56693281, COSV56699762; called by muse, mutect2, varscan2
- PLOD2 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs770629844; called by muse, mutect2
- POFUT2 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.193); catalogued as COSV57959614; called by muse, mutect2, varscan2
- POLQ | c.6566C>T p.A2189V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as COSV51754703; called by muse, mutect2, varscan2
- PRDM7 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as COSV57987064; called by muse, mutect2, varscan2
- PRKAA1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV57184872; called by muse, mutect2, varscan2
- PSMD1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV58078596, COSV58080191; called by muse, mutect2, varscan2
- PTPRH | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as COSV54746802; called by muse, varscan2
- PXDN | c.4155C>G p.F1385L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53238224, COSV99413588; called by muse, mutect2, varscan2
- QPCT | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV58120200; called by muse, mutect2, varscan2
- RABGAP1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV100438669; called by muse, mutect2
- RABGAP1L | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 10/193 reads (5%) | catalogued as COSV99273621; called by muse, mutect2
- RAD54L | c.4-1G>C p.X2_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV64336356; called by muse, mutect2, varscan2
- RAPGEF6 | c.3931G>C p.E1311Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as rs1345366037, COSV99724947; called by muse, mutect2
- RASAL3 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV59140127; called by muse, mutect2, varscan2
- RCC2 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64906010; called by muse, mutect2, varscan2
- RGS2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52459278, COSV99343488; called by muse, mutect2, varscan2
- RIPOR2 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99429981; called by muse, mutect2
- RMDN3 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV53024505; called by muse, mutect2, varscan2
- RNF138 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55234589; called by muse, mutect2, varscan2
- RNF144B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV52570703; called by muse, mutect2, varscan2
- RNF38 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99425309; called by muse, mutect2
- RNGTT | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 19/214 reads (9%) | catalogued as COSV55646222, COSV55656779; called by muse, mutect2
- RPL27A | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58484587; called by mutect2, varscan2
- RPN1 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1169591268, COSV99957232; called by muse, mutect2
- RWDD3 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV55722261; called by muse, mutect2, varscan2
- RYR2 | c.3339G>C p.M1113I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV63692951; called by muse, mutect2, varscan2
- RYR3 | c.11131G>C p.E3711Q (on ENST00000389232; = p.E3712Q on NM_001036.6) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66796099; called by muse, mutect2, varscan2
- SAMD3 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs1450920230; called by muse, mutect2
- SAMHD1 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53430585, COSV99484071; called by muse, mutect2, varscan2
- SCN10A | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV71861870; called by muse, mutect2, varscan2
- SEC14L1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66723099; called by muse, mutect2, varscan2
- SEC31A | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV58875954; called by muse, mutect2, varscan2
- SEMA5B | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.568); catalogued as COSV52101248; called by muse, mutect2, varscan2
- SH3D19 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs760227385, COSV58791422; called by muse, mutect2, varscan2
- SH3GL1 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs369351554; called by muse, mutect2, varscan2
- SIGMAR1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449593; called by muse, mutect2
- SIX2 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57391345; called by muse, mutect2, varscan2
- SLC16A12 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57951247; called by muse, mutect2, varscan2
- SLC25A18 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV53658680; called by muse, mutect2, varscan2
- SLC35F5 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.011); catalogued as COSV55516691, COSV55518936; called by muse, mutect2, varscan2
- SLC39A10 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62768013; called by muse, mutect2, varscan2
- SLC4A1AP | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1249104576, COSV58135549; called by muse, mutect2, varscan2
- SLC6A19 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV57255637; called by muse, mutect2
- SMTNL2 | c.650C>T p.S217L (on ENST00000389313 / NM_001114974.2; = p.S73L on NM_198501.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV58808528; called by muse, mutect2, varscan2
- SMYD3 | c.1214G>T p.G405V (on ENST00000490107 / NM_001375962.1; = p.G346V on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63627595; called by muse, mutect2, varscan2
- SP1 | c.595G>C p.D199H (on ENST00000327443 / NM_138473.3; = p.D192H on NM_003109.1) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59403760; called by muse, mutect2, varscan2
- SPATA31E1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV57792898; called by muse, mutect2, varscan2
- SPHKAP | c.2408G>C p.G803A | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV60883636; called by muse, mutect2, varscan2
- SPTA1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100935462, COSV63758652; called by muse, mutect2
- SPTAN1 | c.3850G>A p.A1284T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63988028; called by muse, mutect2, varscan2
- SUV39H1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.098); catalogued as COSV61920931; called by muse, mutect2, varscan2
- SYNE1 | c.997G>C p.D333H (on ENST00000367255 / NM_182961.4; = p.D340H on NM_033071.3) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55017665; called by muse, mutect2, varscan2
- TACR1 | c.495G>C p.Q165H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59482907; called by muse, mutect2, varscan2
- TAF1 | c.3532C>T p.R1178W (on ENST00000373790 / NM_138923.4; = p.R1199W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52116682; called by muse, mutect2, varscan2
- TDRD6 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV60176580; called by muse, mutect2, varscan2
- TECTA | c.5635G>A p.A1879T | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as rs766297094, COSV50696560; called by muse, mutect2, varscan2
- TENT2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV57137928; called by muse, mutect2, varscan2
- TEX11 | c.1087G>A p.E363K (on ENST00000344304; = p.E348K on NM_031276.3) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.07); catalogued as COSV60233039; called by muse, mutect2, varscan2
- THBS2 | c.1422G>C p.K474N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV64679831, COSV64680779; called by muse, mutect2
- TINAGL1 | c.787G>C p.D263H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV54699320; called by muse, mutect2, varscan2
- TMEM141 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.971); catalogued as COSV51567234; called by muse, mutect2, varscan2
- TMEM143 | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV53157192; called by muse, mutect2, varscan2
- TMEM41B | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV55155646; called by muse, mutect2, varscan2
- TMEM9 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1266194054, COSV100947445; called by muse, mutect2
- TMOD2 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51044986; called by muse, mutect2, varscan2
- TRIO | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60086282; called by muse, mutect2, varscan2
- TRMT10B | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV53050607; called by muse, mutect2, varscan2
- TRMT13 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61582870, COSV61583217; called by muse, mutect2, varscan2
- TRRAP | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 180/204 reads (88%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV62847164; called by muse, mutect2, varscan2
- TRRAP | c.5356G>C p.E1786Q (on ENST00000359863 / NM_001244580.1; = p.E1768Q on NM_003496.3) | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV62840253; called by muse, mutect2
- TRRAP | c.5494C>G p.L1832V (on ENST00000359863 / NM_001244580.1; = p.L1814V on NM_003496.3) | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100722848, COSV62841419; called by muse, mutect2
- TSR2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV64308994; called by muse, mutect2, varscan2
- TULP4 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65577079; called by muse, mutect2, varscan2
- TULP4 | c.3616C>G p.P1206A | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV100893786; called by muse, mutect2
- TXNDC17 | c.312del p.K104Nfs*3 | Frame Shift Del (DEL) | VAF 63/96 reads (66%) | catalogued as rs757868452; called by mutect2, pindel, varscan2
- TYRO3 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV55484277; called by muse, mutect2, varscan2
- UBE2F | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV99800410; called by muse, mutect2
- UNK | c.361C>A p.H121N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53143287; called by muse, mutect2, varscan2
- USH2A | c.12273G>A p.M4091I | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs751834009, COSV56389054, COSV56423895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP37 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as COSV51444569, COSV99294011, COSV99294569; called by muse, mutect2, varscan2
- VEGFB | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100374947; called by muse, mutect2
- VIM | c.1313C>G p.S438* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV56406376; called by muse, mutect2, varscan2
- VPS13B | c.5789G>C p.R1930T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100663313; called by muse, mutect2, varscan2
- WASHC2A | c.1586C>G p.S529* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | catalogued as COSV99254760; called by muse, mutect2
- XPNPEP1 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59169087; called by muse, mutect2, varscan2
- YWHAE | c.698C>G p.S233* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV51983358; called by muse, mutect2, varscan2
- ZBP1 | c.329-1G>A p.X110_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV59062567; called by muse, mutect2, varscan2
- ZCCHC8 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60318843; called by muse, mutect2, varscan2
- ZFHX4 | c.6625G>C p.D2209H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV51450015, COSV51486008; called by muse, mutect2, varscan2
- ZFP14 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54203046; called by muse, mutect2, varscan2
- ZFR | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54054704; called by muse, mutect2, varscan2
- ZGPAT | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58874345; called by muse, varscan2
- ZGPAT | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV58874347; called by muse, varscan2
- ZMAT2 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); catalogued as COSV51227154; called by muse, mutect2, varscan2
- ZMPSTE24 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV65639684; called by muse, mutect2, varscan2
- ZMYM1 | c.3076G>T p.E1026* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV63252303; called by muse, mutect2, varscan2
- ZNF223 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV71571937; called by muse, mutect2, varscan2
- ZNF34 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV58640087; called by muse, mutect2, varscan2
- ZNF467 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs560346109, COSV57371933; called by muse, mutect2
- ZNF483 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.895); catalogued as rs141609552; called by mutect2, varscan2
- ZNF585A | c.256G>C p.A86P (on ENST00000292841 / NM_001288800.2; = p.A31P on NM_152655.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53064884; called by muse, mutect2, varscan2
- ZNF689 | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1478628066, COSV54908960; called by muse, mutect2, varscan2
- ZNF780B | c.2235C>G p.I745M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV55465449, COSV55469023; called by muse, mutect2, varscan2
- ABCA8 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP9 | c.8975G>C p.G2992A (on ENST00000359028; = p.G2968A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); called by muse, mutect2
- ARPP21 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- BACH2 | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CARD6 | c.3080C>G p.S1027* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- CCDC60 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- CCNO | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- CCT7 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COG5 | c.1750G>C p.E584Q (on ENST00000347053 / NM_001379512.1; = p.E605Q on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CTNNA1 | c.748_750dup p.Q250dup | In Frame Ins (INS) | VAF 20/79 reads (25%) | called by mutect2, varscan2
- CUTC | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- DUSP7 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- DVL3 | c.877_879del p.I293del | In Frame Del (DEL) | VAF 29/38 reads (76%) | called by mutect2, pindel, varscan2
- FAM107A | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120C | c.1425G>C p.L475F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- FEZ2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- GBF1 | c.1881G>C p.E627D (on ENST00000369983 / NM_001377137.1; = p.E626D on NM_004193.3) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2
- GUSB | c.968C>G p.P323R | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- HTR2B | c.250_252del p.K84del | In Frame Del (DEL) | VAF 23/96 reads (24%) | called by pindel, varscan2
- KPTN | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- LMCD1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LRRC8B | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MCM7 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.678); called by muse, mutect2
- NLRP13 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- NPEPPS | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF2 | c.565_567del p.E189del (on ENST00000434106 / NM_153433.2; = p.E165del on NM_002540.5 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 22/57 reads (39%) | called by pindel, varscan2
- OR2T8 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PLAT | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, varscan2
- SCN3A | c.4958C>T p.P1653L | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SCN7A | c.1314G>C p.M438I | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2
- SEMA6C | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2
- SEMA6C | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SGSM1 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.146); called by muse, mutect2
- SLC4A2 | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SPATA32 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- TCHH | c.4540G>C p.E1514Q | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRAV9-1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TRIM47 | c.1572G>C p.W524C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.37); called by muse, mutect2
- UMODL1 | c.1454_1455del p.P485Hfs*14 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- VPS50 | c.1870A>C p.M624L | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2
- VWA3B | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2
- ZNF354C | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2
- ABCA1 | c.951G>A p.L317= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV66067615; called by muse, mutect2, varscan2
- ABCA6 | c.3240C>T p.F1080= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs771846160, COSV52640468; called by muse, mutect2, varscan2
- AC068580.4 | c.72C>T p.I24= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52588735; called by muse, mutect2, varscan2
- ACO1 | c.2487C>T p.L829= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1191523702, COSV59381048; called by muse, mutect2, varscan2
- AKAP13 | c.1110G>A p.R370= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV63461899; called by muse, mutect2
- ARSG | c.1362G>A p.L454= | Silent (SNP) | VAF 59/115 reads (51%) | catalogued as COSV50930428; called by muse, mutect2, varscan2
- ATAD3A | c.867G>A p.V289= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- CACNA2D2 | c.2511G>A p.L837= (on ENST00000479441 / NM_001174051.3; = p.L830= on NM_006030.4) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV56565201; called by muse, mutect2, varscan2
- CAMSAP1 | c.2047C>T p.L683= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs889932759; called by muse, mutect2, varscan2
- CCT6A | c.1587G>A p.L529= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV51906337; called by muse, mutect2, varscan2
- CDK11B | c.30G>C p.V10= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV99327744; called by muse, mutect2
- CFAP43 | c.2127C>T p.V709= | Silent (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- CFAP61 | c.870C>T p.L290= | Silent (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- CLIP1 | c.3726C>G p.L1242= (on ENST00000620786 / NM_001247997.1; = p.L1231= on NM_002956.2) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV56803738; called by muse, mutect2, varscan2
- CLPTM1L | c.1616G>A p.*539= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as rs1210076197, COSV100307305; called by muse, mutect2
- COG5 | c.1386C>T p.L462= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1334799317, COSV51755129; called by muse, mutect2, varscan2
- CYP4F11 | c.12G>C p.L4= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs754704954, COSV99931082; called by muse, mutect2
- DCP1B | c.279C>T p.F93= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV54970151; called by muse, mutect2, varscan2
- DYNC2LI1 | c.495G>T p.P165= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV53184012; called by muse, mutect2, varscan2
- FAT3 | c.7242C>A p.T2414= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1404978049, COSV53130315; called by muse, mutect2, varscan2
- FLG2 | c.3702G>A p.G1234= | Silent (SNP) | VAF 12/217 reads (6%) | catalogued as COSV101166146; called by muse, mutect2
- FLT3 | c.1770C>T p.F590= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs141380985, COSV54064789; called by muse, mutect2, varscan2
- FMNL1 | c.2244C>T p.F748= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs750629266, COSV58955487; called by muse, mutect2, varscan2
- FNDC3A | c.3504G>A p.L1168= (on ENST00000492622 / NM_001079673.2; = p.L1112= on NM_014923.5) | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1371894922, COSV68133835; called by muse, mutect2, varscan2
- FRAS1 | c.8454G>A p.K2818= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53621368; called by muse, mutect2, varscan2
- GRPR | c.120C>G p.L40= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV66669714; called by muse, mutect2, varscan2
- HKDC1 | c.42G>C p.L14= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV63577774; called by muse, mutect2, varscan2
- HSPA1L | c.1083C>T p.L361= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV65148853, COSV65149174; called by muse, mutect2, varscan2
- IL17REL | c.27G>T p.L9= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- IL4R | c.174C>T p.L58= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV50149514; called by muse, mutect2, varscan2
- INS | c.276G>A p.V92= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV51747617; called by muse, mutect2, varscan2
- INSR | c.1749C>G p.L583= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV57164651; called by muse, mutect2, varscan2
- INTS1 | c.6201G>C p.L2067= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV67178087; called by muse, mutect2, varscan2
- LEPROT | c.186C>T p.T62= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as COSV60757635; called by muse, mutect2, varscan2
- LRFN5 | c.1491C>T p.L497= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53255132, COSV53262507; called by muse, mutect2, varscan2
- MAGEB16 | c.489G>A p.E163= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV67874121; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2145G>A p.L715= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV51722007; called by muse, mutect2, varscan2
- MCTP2 | c.144C>T p.L48= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV59145881; called by muse, mutect2, varscan2
- MED12 | c.4161C>T p.I1387= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as rs776947543, COSV61344303; ClinVar: likely benign; called by muse, mutect2, varscan2
- MED13L | c.1953C>T p.L651= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV56123034; called by muse, mutect2, varscan2
- MIP | c.372G>A p.A124= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs141768870; called by mutect2, varscan2
- MMS19 | c.2802C>G p.L934= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV59136033; called by muse, mutect2, varscan2
- MYH11 | c.3432C>T p.L1144= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs145289672; ClinVar: likely benign; called by muse, mutect2, varscan2
- OTOF | c.387C>T p.D129= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs761367436, COSV55494733; called by muse, mutect2, varscan2
- PCDH15 | c.3723C>T p.S1241= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs748083366, COSV57277599, COSV57335453; called by muse, mutect2, varscan2
- PCDHA7 | c.1893C>T p.I631= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs558998530, COSV65345082; called by muse, mutect2, varscan2
- PHF1 | c.1128G>A p.L376= (on ENST00000374516 / NM_024165.3; = p.E373K on NM_002636.5) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100992665; called by muse, mutect2
- PHF8 | c.3178C>T p.L1060= (on ENST00000357988 / NM_001184896.1; = p.L1024= on NM_015107.3) | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV57678798; called by muse, mutect2
- PLAT | c.1182C>A p.V394= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, varscan2
- PRDM4 | c.1932G>A p.K644= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV57306375; called by muse, varscan2
- PSMC1 | c.318G>A p.P106= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs981186048; called by muse, mutect2, varscan2
- QSER1 | c.2046C>A p.L682= (on ENST00000399302; = p.L811= on NM_001076786.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV67901019; called by muse, mutect2, varscan2
- RALGAPA2 | c.4740C>T p.F1580= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs780044972, COSV52491071; called by muse, mutect2, varscan2
- RAPGEF4 | c.414C>T p.I138= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1442027973, COSV51381291, COSV51397803; called by muse, mutect2, varscan2
- RNF213 | c.8385C>T p.L2795= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100301333; called by muse, mutect2
- RNF213 | c.12702C>T p.L4234= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- SAMD9L | c.87T>A p.I29= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- SCUBE1 | c.417C>T p.Y139= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs748542019, COSV51812958; called by muse, mutect2, varscan2
- SLC12A3 | c.1770C>G p.L590= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52636321; called by muse, mutect2, varscan2
- SLC25A44 | c.210C>T p.I70= | Silent (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- SLC25A46 | c.663G>A p.L221= | Silent (SNP) | VAF 36/218 reads (17%) | catalogued as rs569124662, COSV63506823; called by muse, mutect2, varscan2
- SLC25A53 | c.465C>T p.F155= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV62459558; called by muse, mutect2, varscan2
- SLC45A4 | c.441C>T p.L147= (on ENST00000517878 / NM_001286646.2; = p.L96= on NM_001080431.2) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs759022110, COSV50143214; called by muse, mutect2, varscan2
- SMAP1 | c.57C>T p.L19= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs748807136, COSV100390869, COSV57641267; called by muse, mutect2, varscan2
- SNX29 | c.1611C>G p.L537= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV60050286; called by muse, mutect2, varscan2
- STIP1 | c.759G>A p.E253= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs1362462758, COSV59439722; called by muse, mutect2, varscan2
- STXBP2 | c.693G>C p.L231= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as CD096289, COSV55403901; called by muse, mutect2, varscan2
- TAF3 | c.1005G>A p.V335= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV60207848; called by muse, mutect2, varscan2
- TAS2R43 | c.306C>A p.L102= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV67857539; called by muse, mutect2, varscan2
- TNN | c.813C>T p.L271= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV53428946; called by muse, mutect2
- TTC16 | c.504G>A p.E168= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100077053; called by muse, mutect2
- TYW5 | c.276G>A p.E92= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100662405, COSV63562528; called by muse, mutect2, varscan2
- UBAP2 | c.2835C>G p.L945= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV54290477; called by muse, mutect2, varscan2
- WDR48 | c.1437G>A p.V479= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV56532657; called by muse, mutect2, varscan2
- XIRP2 | c.6330T>C p.S2110= (on ENST00000628543; = p.S2285= on NM_152381.6) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54710581, COSV99748167; called by muse, mutect2, varscan2
- ZBTB17 | c.1290C>T p.P430= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV65270455; called by muse, mutect2, varscan2
- ZNF519 | c.459C>T p.V153= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV73913444; called by muse, mutect2, varscan2
- ZNF568 | c.282G>C p.P94= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV61741952; called by muse, mutect2, varscan2
- ZNF786 | c.1488G>A p.L496= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60276757; called by muse, mutect2, varscan2
- ZNF92 | c.195G>C p.L65= | Silent (SNP) | VAF 29/696 reads (4%) | called by muse, mutect2
- ZSCAN20 | c.612C>T p.L204= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs771393935, COSV63683274; called by muse, mutect2, varscan2
- AK6 | chr5:69369666 G>C | 5'Flank (SNP) | VAF 15/85 reads (18%) | catalogued as COSV51458360; called by muse, mutect2, varscan2
- C3P1 | n.2515G>C | RNA (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- EXD1 | c.-1G>A | 5'UTR (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100153809; called by muse, mutect2, varscan2
- GP6 | c.*611G>A | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59978209; called by muse, mutect2
- IKBIP | c.297+8031G>A | Intron (SNP) | VAF 32/93 reads (34%) | catalogued as rs1328624583, COSV54488714; called by muse, mutect2, varscan2
- VWA2 | c.2122+55G>C | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
